Somatic mutation profile of tumor specimen TCGA-AB-2881-03A (aliquot TCGA-AB-2881-03A-01W-0732-08) from TCGA case TCGA-AB-2881, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.8 years (17,808 days).
Specimen TCGA-AB-2881-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93b9c98c-f06a-4e01-a05e-6afb756972b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2881-11A (Solid Tissue Normal), aliquot TCGA-AB-2881-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/025945dc-88f2-4a9e-80b0-616223752bec

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTCL1 | c.3449G>A p.R1150H (on ENST00000306329 / NM_001378206.1; = p.R831H on NM_015210.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs199934266; called by mutect2, varscan2
- HSH2D | c.522delinsCTCC p.S175dup | In Frame Ins (INS) | VAF 9/98 reads (9%) | called by pindel, varscan2*
